Somatic mutation profile of tumor specimen f9d6fb1b-988e-4d28-9272-cc672f (aliquot f9d6fb1b-988e-4d28-9272-cc672f_D6) from CPTAC case 01CO006, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC.
Specimen f9d6fb1b-988e-4d28-9272-cc672f: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab98d030-f800-4452-a59c-12ad297ff074.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen a354b1e9-7813-4274-957c-5e1768 (Blood Derived Normal), aliquot a354b1e9-7813-4274-957c-5e1768_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fadc156-cc76-4635-b5c4-f41fb900984d

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.2128C>T p.R710C | Missense Mutation (SNP) | VAF 17/350 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60703101; called by muse, mutect2
- MAP7D3 | c.1405G>T p.A469S | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60170053; called by muse, mutect2
- REV1 | c.201G>T p.L67F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51486023; called by muse, mutect2
- BIRC6 | c.4453C>A p.L1485I | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); called by muse, mutect2
- CCNG2 | c.108A>G p.K36= | Silent (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- IGHE | c.114G>A p.P38= | Silent (SNP) | VAF 22/375 reads (6%) | catalogued as rs371479236; called by muse, mutect2
- SLC29A3 | c.*271T>C | 3'UTR (SNP) | VAF 24/706 reads (3%) | called by muse, mutect2
